Somatic mutation profile of tumor specimen C3N-02431-02 (aliquot CPT0183360007) from CPTAC case C3N-02431, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 47.4 years (17,309 days).
Specimen C3N-02431-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec7ae8cb-f46c-4db0-95fa-609780e2f0cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02431-71 (Blood Derived Normal), aliquot CPT0183410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46ab9ef2-b7be-4cc4-bd89-00ccea230aa4

The open-access MAF lists 60 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Intron 3, In Frame Del 3, Nonsense Mutation 2, RNA 2, Frame Shift Del 2, Splice Site 2, 3'Flank 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMMECR1 | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.599); catalogued as rs1290770764; called by muse, mutect2
- DNM2 | c.320G>C p.R107T | Missense Mutation (SNP) | VAF 70/452 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58967799; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.349A>C p.S117R (on ENST00000485419 / NM_001197113.1; = p.S41R on NM_014575.3) | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs749960330, COSV100541097; called by muse, varscan2
- KIF1B | c.1005T>A p.D335E (on ENST00000377086 / NM_001365952.1; = p.D329E on NM_015074.3) | Missense Mutation (SNP) | VAF 60/506 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV55811638; called by muse, mutect2, varscan2
- MUC12 | c.1774A>G p.T592A (on ENST00000379442; = p.T449A on NM_001164462.1) | Missense Mutation (SNP) | VAF 74/1504 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs1364398716; called by muse, mutect2
- NDUFS3 | c.68-2A>G p.X23_splice | Splice Site (SNP) | VAF 88/640 reads (14%) | catalogued as rs1416590744, COSV99772275; called by muse, mutect2, varscan2
- PTCH1 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 79/606 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs370354759, CM066196, COSV59465475; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIMS2 | c.3346G>A p.D1116N (on ENST00000666250 / NM_001348490.2; = p.D924N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.644); catalogued as COSV51653992; called by muse, mutect2, varscan2
- RMDN3 | c.738C>G p.D246E | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs774398653, COSV99539795; called by muse, mutect2, varscan2
- RYR2 | c.11413C>G p.L3805V | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV63680663; called by muse, mutect2, varscan2
- SOGA1 | c.3381G>C p.E1127D | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs574609446; called by muse, mutect2, varscan2
- TP53 | c.794T>A p.L265Q | Missense Mutation (SNP) | VAF 89/660 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD004355, CM971505, COSV52706540, COSV52732531, COSV53696163; called by muse, mutect2, varscan2
- VHL | c.388G>T p.V130F | Missense Mutation (SNP) | VAF 50/373 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104893830, CM031394, CM126148, CM961427, COSV56543368, COSV56544519, COSV56551325, COSV56566091; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ZNHIT1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs376183663, COSV100521923; called by muse, mutect2, varscan2
- ARHGEF9 | c.1295A>C p.K432T | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- BAG6 | c.1481dup p.E495* | Frame Shift Ins (INS) | VAF 42/289 reads (15%) | called by mutect2, varscan2
- CCT8 | c.669T>A p.F223L | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CPN2 | c.803C>A p.T268N | Missense Mutation (SNP) | VAF 82/522 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- CT83 | c.224_244del p.A75_L81del | In Frame Del (DEL) | VAF 18/186 reads (10%) | called by mutect2, pindel
- ENPP2 | c.688G>T p.G230C | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FTSJ3 | c.146T>A p.L49Q | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- GSX1 | c.485T>G p.L162R | Missense Mutation (SNP) | VAF 45/307 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIPI | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LTBP3 | c.3761-2dup p.X1254_splice (on ENST00000301873 / NM_001130144.3; = p.X1207_splice on NM_021070.4 and 1 other RefSeq transcript) | Splice Site (INS) | VAF 64/590 reads (11%) | called by mutect2, varscan2
- MPHOSPH8 | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO18B | c.4652A>G p.K1551R | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PAPPA2 | c.875_880del p.W292_K294delins* | Nonsense Mutation (DEL) | VAF 26/198 reads (13%) | called by mutect2, pindel
- PCDHGB7 | c.255_269del p.V86_I90del | In Frame Del (DEL) | VAF 78/531 reads (15%) | called by mutect2, varscan2
- PLEC | c.11582_11602del p.L3861_G3868delinsR (on ENST00000322810 / NM_201380.4; = p.L3751_G3758delinsR on NM_000445.5) | In Frame Del (DEL) | VAF 62/478 reads (13%) | called by mutect2, pindel
- PLEKHH2 | c.1898G>T p.S633I | Missense Mutation (SNP) | VAF 37/326 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- PPP2R2A | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- SLC30A10 | c.629C>G p.A210G | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC35G2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 31/290 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- TCTN1 | c.1562A>G p.N521S (on ENST00000551590 / NM_001173975.3; = p.N507S on NM_024549.6) | Missense Mutation (SNP) | VAF 74/562 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THBS2 | c.2571_2581del p.C858Rfs*5 | Frame Shift Del (DEL) | VAF 34/354 reads (10%) | called by mutect2, pindel
- TLE1 | c.1104T>A p.Y368* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2
- UBE2Q2 | c.537T>G p.N179K | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2
- VPS13C | c.2732T>A p.L911H (on ENST00000644861 / NM_020821.3; = p.L868H on NM_017684.5) | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- VSIR | c.902C>G p.P301R | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2
- XKR5 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 69/521 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- ZDHHC5 | c.1243del p.S415Vfs*81 | Frame Shift Del (DEL) | VAF 40/327 reads (12%) | called by mutect2, pindel, varscan2
- ZNF250 | c.1477A>G p.T493A | Missense Mutation (SNP) | VAF 54/411 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF92 | c.1691C>G p.P564R (on ENST00000328747 / NM_152626.4; = p.P495R on NM_007139.4) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.378); called by muse, varscan2
- BACE2 | c.1038G>A p.T346= | Silent (SNP) | VAF 38/282 reads (13%) | catalogued as rs138316153, COSV100160590; called by muse, mutect2, varscan2
- CCDC170 | c.1029C>T p.S343= | Silent (SNP) | VAF 39/239 reads (16%) | catalogued as rs55867829; called by muse, mutect2, varscan2
- IGF2R | c.2743C>T p.L915= | Silent (SNP) | VAF 33/316 reads (10%) | catalogued as rs1475699725; called by muse, mutect2, varscan2
- OR6N2 | c.426C>A p.A142= | Silent (SNP) | VAF 33/304 reads (11%) | catalogued as COSV59413212; called by muse, mutect2, varscan2
- PDCD6 | c.144T>A p.L48= | Silent (SNP) | VAF 22/184 reads (12%) | called by muse, mutect2, varscan2
- PDE6C | c.543A>G p.A181= | Silent (SNP) | VAF 88/645 reads (14%) | called by muse, mutect2, varscan2
- PRUNE2 | c.5976T>C p.G1992= | Silent (SNP) | VAF 38/257 reads (15%) | called by muse, mutect2, varscan2
- RNF169 | c.609C>A p.P203= | Silent (SNP) | VAF 27/168 reads (16%) | called by muse, mutect2, varscan2
- TCTN3 | c.216T>A p.T72= | Silent (SNP) | VAF 67/563 reads (12%) | called by muse, mutect2, varscan2
- VHL | c.387G>T p.L129= | Silent (SNP) | VAF 51/375 reads (14%) | catalogued as rs778846471, COSV56561103, COSV56563271; ClinVar: likely benign; called by muse, mutect2, varscan2
- C3orf35 | n.1434T>A | RNA (SNP) | VAF 40/220 reads (18%) | called by muse, mutect2, varscan2
- MICAL3 | c.2802-2402del | Intron (DEL) | VAF 24/152 reads (16%) | called by mutect2, pindel*
- MIR146A | n.64A>T | RNA (SNP) | VAF 21/166 reads (13%) | called by muse, mutect2, varscan2
- PPM1B | chr2:44232339 A>G | 3'Flank (SNP) | VAF 12/139 reads (9%) | called by muse, mutect2
- RPL4 | c.176-92G>A | Intron (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- SMIM7 | c.*44G>A | 3'UTR (SNP) | VAF 29/206 reads (14%) | called by muse, mutect2, varscan2
- SV2C | c.581-21185T>A | Intron (SNP) | VAF 54/378 reads (14%) | called by muse, mutect2, varscan2
